Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8EO, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8EO-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell
NOS 807013
Site: Esophagus, distal
third C15.5
JW 1/24/14

Collect date:
(MM/DD/YYYY)

PRIMARY SITE: Esophagus (Mid and distal third)

PATHOLOGY REPORT:

Specimen: Esophagus and proximal stomach
Procedure: Esophagectomy and partial gastrectomy
Tumor site: esophagus
Tumor size (greatest dimension): 6.7 cm
Histologic type: Squamous cell carcinoma, ulcerated,
Histologic grade: G3 poorly differentiated
Microscopic tumor extension: tumor invades through muscularis propria into the
adventitia
Lymph-vascular invasion: present
Perineural invasion: not identified
Margins: uninvolved by carcinoma
Regional lymph nodes:
Number examined: 08
Number positive for neoplasia: 00

Source: NCI Genomic Data Commons file 31fad782-411d-4cf5-8eed-dedf14e91521 (TCGA-VR-A8EO.1063C12D-8DD7-4C1E-801E-C2046664DC16.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).